Somatic mutation profile of tumor specimen C3L-02644-02 (aliquot CPT0227810007) from CPTAC case C3L-02644, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.1 years (21,234 days).
Specimen C3L-02644-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85cc09c4-ebe8-4d6b-8988-35e9ae209cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02644-31 (Blood Derived Normal), aliquot CPT0227900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c034a9e6-d183-4b8a-ab61-f89df0d33d46

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 10, Intron 7, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, 3'Flank 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs761336289; called by muse, mutect2, varscan2
- ADCY5 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1336832799, COSV59200260; called by muse, mutect2, varscan2
- ATPAF2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 116/728 reads (16%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.849); catalogued as rs752203704; called by muse, mutect2, varscan2
- CAPN1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs1565385504; called by muse, varscan2
- CCR1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1192919970; called by muse, mutect2, varscan2
- CPAMD8 | c.2152C>T p.R718C (on ENST00000651564; = p.R671C on NM_015692.5) | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374988485, COSV99358983; called by muse, mutect2, varscan2
- ENSA | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.621); catalogued as rs1228754399; called by muse, mutect2, varscan2
- FAM83H | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs371718430; called by muse, mutect2, varscan2
- FFAR3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 124/602 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs751901197; called by muse, mutect2
- GOT1L1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs759504357; called by muse, mutect2, varscan2
- IL18R1 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as rs765825588; called by muse, mutect2, varscan2
- LCT | c.5335G>A p.A1779T | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99928472; called by muse, mutect2, varscan2
- LRRC75B | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs765867399; called by muse, mutect2, varscan2
- MEGF11 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs554311397; called by muse, mutect2
- NLRP1 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52568451; called by muse, mutect2, varscan2
- NLRP5 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs367708838; called by muse, mutect2
- NTRK1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 133/378 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs199826686, COSV62328420; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2
- PCDHGA1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 45/494 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65294825, COSV65298907; called by muse, mutect2
- PER2 | c.3655A>G p.I1219V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1460554878; called by muse, mutect2, varscan2
- PIK3C3 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs766344105, COSV56281784; called by muse, mutect2, varscan2
- QKI | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as rs1241329794; called by muse, mutect2, varscan2
- REPIN1 | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 102/443 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68291855; called by muse, mutect2, varscan2
- SEMA3A | c.912T>G p.H304Q | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs749429274; called by muse, mutect2, varscan2
- SERPINA7 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59666422; called by muse, mutect2, varscan2
- SPTA1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 107/334 reads (32%) | catalogued as rs764157190, COSV63751440; called by muse, mutect2, varscan2
- TARBP1 | c.1961+1G>T p.X654_splice | Splice Site (SNP) | VAF 33/92 reads (36%) | catalogued as rs752846796; called by muse, mutect2, varscan2
- TDRD5 | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268703808, COSV54239357; called by muse, mutect2, varscan2
- TP53 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM1412385, COSV52675923, COSV52730390; called by muse, mutect2, varscan2
- VPS37C | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as rs375223987; called by muse, mutect2, varscan2
- ZFYVE28 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs543648457, COSV52109549, COSV52117899; called by muse, mutect2, varscan2
- ZNF689 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs922399902; called by muse, mutect2, varscan2
- ALKBH6 | c.190C>G p.L64V (on ENST00000252984 / NM_001297701.2; = p.L92V on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- CEP76 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CROCC2 | c.2431C>G p.Q811E | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CTU1 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DHX8 | c.864-2A>G p.X288_splice | Splice Site (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- F13A1 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HLA-A | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIAA0825 | c.3183C>A p.D1061E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB16 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- NLRP1 | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP1 | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 95/283 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OR5K3 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- P2RY8 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 132/369 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHF14 | c.1978A>G p.K660E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PIK3R1 | c.1369C>A p.Q457K (on ENST00000521381 / NM_181523.3; = p.Q187K on NM_181504.4) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- POU4F1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- PPP6R2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PUS7 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIT2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S1PR5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UPF3A | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- USP39 | c.34del p.S12Pfs*39 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- COG1 | c.1980C>A p.I660= | Silent (SNP) | VAF 117/386 reads (30%) | catalogued as rs773468672, COSV100245422; called by muse, mutect2, varscan2
- GABRG2 | c.372A>G p.R124= | Silent (SNP) | VAF 79/221 reads (36%) | called by muse, mutect2, varscan2
- KRT15 | c.879C>T p.V293= | Silent (SNP) | VAF 70/174 reads (40%) | catalogued as rs764050371, COSV54178811; called by muse, mutect2, varscan2
- MYO1B | c.942C>A p.G314= | Silent (SNP) | VAF 54/161 reads (34%) | called by muse, mutect2, varscan2
- NYAP2 | c.261C>T p.Y87= | Silent (SNP) | VAF 87/250 reads (35%) | catalogued as rs376065085; called by muse, mutect2, varscan2
- OR51E1 | c.729C>T p.C243= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs144348112; called by muse, mutect2, varscan2
- PDZD2 | c.2661C>T p.D887= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs756642743, COSV99227242; called by muse, mutect2, varscan2
- SLC6A12 | c.285G>A p.A95= | Silent (SNP) | VAF 85/282 reads (30%) | catalogued as rs376674831; called by muse, mutect2, varscan2
- ZNF727 | c.276C>T p.N92= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs558951518, COSV70702522; called by muse, mutect2, varscan2
- ZNF729 | c.453A>G p.R151= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.1358-744A>G | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- GUCY2EP | n.209C>T | RNA (SNP) | VAF 7/62 reads (11%) | catalogued as rs985520507; called by muse, mutect2, varscan2
- IQCE | c.1632+64G>A | Intron (SNP) | VAF 40/199 reads (20%) | catalogued as rs1242797029; called by muse, mutect2, varscan2
- LTO1 | c.346-722G>A | Intron (SNP) | VAF 61/170 reads (36%) | called by muse, mutect2, varscan2
- MAGOHB | c.94+502C>A | Intron (SNP) | VAF 45/145 reads (31%) | catalogued as rs1241564075; called by muse, mutect2, varscan2
- MAPK15 | c.780-136G>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1418382630; called by muse, varscan2
- MICOS10 | c.223-981G>T | Intron (SNP) | VAF 74/206 reads (36%) | called by muse, mutect2, varscan2
- SETDB2 | chr13:49443996 A>G | 5'Flank (SNP) | VAF 55/159 reads (35%) | catalogued as rs1453031581; called by muse, mutect2, varscan2
- SYT14 | c.61+484A>T | Intron (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- VAX1 | chr10:117132247 G>A | 3'Flank (SNP) | VAF 48/97 reads (49%) | catalogued as rs769637738, COSV53331498; called by muse, mutect2, varscan2
